Gene-level copy-number profile of tumor specimen TCGA-B5-A11G-01A from TCGA case TCGA-B5-A11G, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 71.2 years (25,995 days).
Specimen TCGA-B5-A11G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.f2786439-cb59-43cf-8e81-3b7af9b60585.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A11G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 367 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd3e0779-974d-4e55-9d57-436857ee7d90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 962; copy number 1: 1,499; copy number 2: 57,557; copy number 3: 107; copy number 4: 87; copy number 9: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A11G-01A-13D-A120-01): tumor purity 0.9, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 442 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:98,251,688–98,443,858, 2 genes (within-gene range 0–2): AC019077.1, RAP1GDS1.
- chr5:21,569,755–25,445,925, 45 genes: AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2.
- chr5:151,276,358–151,303,766, 1 gene (within-gene range 0–2): SLC36A3.
- chr10:6,682,513–27,542,239, 332 genes (within-gene range 0–2) (broad region; genes not listed).
- chr13:62,672,285–71,297,235, 60 genes (within-gene range 0–2): LINC00448, AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1, LGMNP1, STARP1, HNRNPA3P5, LINC01052, AL158038.1, MIR548X2, MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1.
- chr16:76,868,936–76,878,936, 2 genes: MIR4719, AC106734.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 44 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 9 (within-gene range 2–9): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr4:49,203,171–49,589,529, 19 genes, copy number 9: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Autosomal genes at a single copy (total copy number 1): 1,498. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
